Somatic mutation profile of tumor specimen MMRF_1817_1_BM_CD138pos (aliquot MMRF_1817_1_BM_CD138pos_T1_KBS5U_L05541) from MMRF case MMRF_1817, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 68.5 years (25,022 days).
Specimen MMRF_1817_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e823d5ce-7207-444f-8476-5c71f0807a99.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1817_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1817_1_PB_Whole_C3_KBS5U_L05568; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1215c2bf-89bc-49c3-93f3-976a0278e1c2

The open-access MAF lists 121 somatic variants for this specimen: 38 protein-altering or splice-affecting, 14 silent, 69 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 48, Missense Mutation 36, Silent 14, Intron 13, RNA 2, 3'Flank 2, 5'UTR 2, 5'Flank 2, Splice Site 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AGTPBP1 | c.3601G>A p.E1201K (on ENST00000357081 / NM_001330701.2; = p.E1161K on NM_015239.2) | Missense Mutation (SNP) | VAF 84/173 reads (49%) | SIFT deleterious (0.02); PolyPhen benign (0.057); catalogued as rs1193022943; called by muse, mutect2, varscan2
- ASXL3 | c.715G>T p.G239W | Missense Mutation (SNP) | VAF 27/70 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV99325243; called by muse, mutect2, varscan2
- CDK3 | c.757C>T p.P253S | Missense Mutation (SNP) | VAF 21/40 reads (53%) | SIFT tolerated (0.07); PolyPhen benign (0.062); catalogued as COSV100043835; called by muse, mutect2, varscan2
- CRIM1 | c.1879C>T p.R627W | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs951475238, COSV54868031, COSV99752082; called by muse, mutect2
- IGHJ4 | c.5T>G p.F2C | Missense Mutation (SNP) | VAF 54/56 reads (96%) | PolyPhen benign (0.071); catalogued as rs1433521247; called by muse, mutect2, varscan2
- IGLV3-1 | c.61T>A p.Y21N | Missense Mutation (SNP) | VAF 59/132 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.137); catalogued as rs372924773; called by muse, mutect2, varscan2
- IGLV3-1 | c.250A>G p.N84D | Missense Mutation (SNP) | VAF 60/132 reads (45%) | SIFT deleterious (0.05); PolyPhen benign (0.03); catalogued as rs369317662; called by muse, varscan2
- MAFK | c.167G>A p.R56Q | Missense Mutation (SNP) | VAF 32/65 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1427084590; called by muse, mutect2, varscan2
- NEGR1 | c.227G>A p.S76N | Missense Mutation (SNP) | VAF 64/667 reads (10%) | SIFT tolerated (0.52); PolyPhen benign (0.124); catalogued as rs760633817, COSV60858700; called by mutect2, varscan2
- NFASC | c.2683C>T p.R895C (on ENST00000339876 / NM_001378329.1; = p.R998C on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 51/98 reads (52%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.983); catalogued as rs747420515, COSV58360694; called by muse, mutect2, varscan2
- OR4M1 | c.592G>A p.V198M | Missense Mutation (SNP) | VAF 18/224 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.831); catalogued as COSV60061052, COSV60061487; called by muse, mutect2
- PKHD1 | c.10464C>A p.N3488K | Missense Mutation (SNP) | VAF 32/205 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.257); catalogued as rs775481784, COSV100945244; called by muse, mutect2, varscan2
- SYCE1 | c.911G>A p.G304E (on ENST00000343131 / NM_001143764.3; = p.G268E on NM_130784.3) | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT tolerated (0.22); PolyPhen benign (0.011); catalogued as COSV58219436; called by muse, mutect2
- ADGRL2 | c.74-2A>T p.X25_splice | Splice Site (SNP) | VAF 50/106 reads (47%) | called by muse, mutect2, varscan2
- BTNL2 | c.1291G>A p.V431M | Missense Mutation (SNP) | VAF 196/403 reads (49%) | SIFT tolerated (0.11); PolyPhen benign (0.378); called by muse, mutect2, varscan2
- C6 | c.994C>G p.L332V | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DLC1 | c.4502G>A p.G1501E (on ENST00000276297 / NM_001348081.2; = p.G1064E on NM_006094.5) | Missense Mutation (SNP) | VAF 22/240 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- DNAH9 | c.2655C>A p.N885K | Missense Mutation (SNP) | VAF 37/120 reads (31%) | SIFT tolerated (0.19); PolyPhen benign (0); called by muse, mutect2, varscan2
- DOCK1 | c.1665G>T p.K555N | Missense Mutation (SNP) | VAF 15/308 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); called by muse, mutect2
- FANCM | c.2722G>T p.A908S | Missense Mutation (SNP) | VAF 5/101 reads (5%) | SIFT tolerated (0.72); PolyPhen benign (0.057); called by muse, mutect2
- FAT1 | c.1350G>T p.L450F | Missense Mutation (SNP) | VAF 17/317 reads (5%) | SIFT tolerated (0.47); PolyPhen benign (0.282); called by muse, mutect2
- FAT4 | c.3565C>G p.P1189A | Missense Mutation (SNP) | VAF 11/199 reads (6%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.04); called by muse, mutect2
- FOXL2 | c.494G>T p.G165V | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.217); called by muse, mutect2, varscan2
- H2AC17 | c.280C>G p.L94V | Missense Mutation (SNP) | VAF 59/120 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.837); called by muse, mutect2, varscan2
- HIF1A | c.166A>C p.K56Q | Missense Mutation (SNP) | VAF 125/254 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KLK6 | c.286C>A p.P96T | Missense Mutation (SNP) | VAF 65/153 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MPPE1 | c.1036C>G p.L346V | Missense Mutation (SNP) | VAF 25/221 reads (11%) | SIFT tolerated (0.28); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- NR1H4 | c.1331T>C p.F444S (on ENST00000551379 / NM_001206993.2; = p.F430S on NM_005123.4) | Missense Mutation (SNP) | VAF 26/218 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PPP3CC | c.131A>G p.N44S | Missense Mutation (SNP) | VAF 70/160 reads (44%) | SIFT tolerated (0.39); PolyPhen benign (0); called by muse, mutect2, varscan2
- PRDM15 | c.2629T>G p.F877V | Missense Mutation (SNP) | VAF 14/128 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PROS1 | c.1412A>T p.Q471L | Missense Mutation (SNP) | VAF 12/150 reads (8%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.702); called by muse, mutect2
- PTEN | c.1136A>T p.Y379F | Missense Mutation (SNP) | VAF 13/215 reads (6%) | SIFT tolerated, low confidence (0.22); PolyPhen probably damaging (0.956); called by muse, mutect2
- PTPN2 | c.1207T>G p.F403V | Missense Mutation (SNP) | VAF 37/125 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- RAD9A | c.96G>C p.L32F | Missense Mutation (SNP) | VAF 35/73 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.343); called by muse, mutect2, varscan2
- RSRC2 | c.241A>C p.K81Q | Missense Mutation (SNP) | VAF 58/113 reads (51%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- SLCO1C1 | c.1125C>A p.Y375* | Nonsense Mutation (SNP) | VAF 15/184 reads (8%) | called by muse, mutect2
- TPP2 | c.518A>T p.E173V | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.583); called by muse, mutect2
- UBR4 | c.8354G>A p.G2785D | Missense Mutation (SNP) | VAF 11/101 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ADARB2 | c.1276C>T p.L426= | Silent (SNP) | VAF 9/80 reads (11%) | called by muse, mutect2, varscan2
- CFAP65 | c.3876G>A p.P1292= | Silent (SNP) | VAF 33/77 reads (43%) | catalogued as rs755517872, COSV58563683; called by muse, mutect2, varscan2
- CPNE6 | c.1329C>T p.D443= | Silent (SNP) | VAF 17/262 reads (6%) | catalogued as rs910624041; called by muse, mutect2
- FBXO41 | c.1473C>G p.S491= | Silent (SNP) | VAF 75/147 reads (51%) | called by muse, mutect2, varscan2
- GFI1B | c.777G>A p.Q259= | Silent (SNP) | VAF 15/244 reads (6%) | catalogued as rs1356951856; called by muse, mutect2
- HECW2 | c.3357A>C p.R1119= | Silent (SNP) | VAF 87/204 reads (43%) | called by muse, mutect2, varscan2
- IGLL5 | c.177C>T p.S59= | Silent (SNP) | VAF 13/28 reads (46%) | catalogued as rs569308745, COSV104440313, COSV73250973; called by muse, mutect2, varscan2
- RCBTB2 | c.1218T>C p.Y406= | Silent (SNP) | VAF 9/33 reads (27%) | called by muse, mutect2, varscan2
- RYR1 | c.108G>A p.L36= | Silent (SNP) | VAF 15/30 reads (50%) | called by muse, mutect2, varscan2
- TENT5A | c.876C>T p.G292= | Silent (SNP) | VAF 61/126 reads (48%) | called by muse, mutect2, varscan2
- TLR4 | c.2130A>G p.R710= (on ENST00000355622 / NM_138554.5; = p.R670= on NM_003266.4) | Silent (SNP) | VAF 38/82 reads (46%) | called by muse, mutect2, varscan2
- TRANK1 | c.8529G>A p.R2843= | Silent (SNP) | VAF 79/150 reads (53%) | called by muse, mutect2, varscan2
- VN1R2 | c.862T>C p.L288= | Silent (SNP) | VAF 18/181 reads (10%) | called by muse, mutect2, varscan2
- VRTN | c.1356G>A p.P452= | Silent (SNP) | VAF 15/108 reads (14%) | catalogued as rs112481247; called by muse, mutect2, varscan2
- ABCB9 | c.-529T>A | 5'UTR (SNP) | VAF 32/74 reads (43%) | called by muse, varscan2
- AFAP1L2 | c.*386G>T | 3'UTR (SNP) | VAF 5/103 reads (5%) | called by muse, mutect2
- ALX4 | c.*3054G>T | 3'UTR (SNP) | VAF 66/135 reads (49%) | called by muse, mutect2, varscan2
- ANO5 | c.*1338_*1339dup | 3'UTR (INS) | VAF 42/102 reads (41%) | catalogued as rs932422843; called by mutect2, varscan2
- ANTXR2 | c.*100G>T | 3'UTR (SNP) | VAF 27/326 reads (8%) | called by muse, mutect2
- BNC2 | chr9:16870770 C>T | 5'Flank (SNP) | VAF 6/53 reads (11%) | called by muse, mutect2, varscan2
- CACNA2D1 | chr7:81947345 G>T | 3'Flank (SNP) | VAF 8/136 reads (6%) | called by muse, mutect2
- CACNB4 | c.148-50C>A | Intron (SNP) | VAF 28/60 reads (47%) | called by muse, mutect2, varscan2
- CAMKK2 | c.*269A>G | 3'UTR (SNP) | VAF 112/371 reads (30%) | catalogued as rs199657939; called by muse, mutect2, varscan2
- CANX | c.*386T>G | 3'UTR (SNP) | VAF 22/48 reads (46%) | called by muse, mutect2, varscan2
- CNOT2 | c.1392-732G>A | Intron (SNP) | VAF 31/79 reads (39%) | called by muse, mutect2, varscan2
- CYP7B1 | chr8:64798875 G>T | 5'Flank (SNP) | VAF 6/124 reads (5%) | called by muse, mutect2
- DGKB | c.-81A>T | 5'UTR (SNP) | VAF 35/364 reads (10%) | called by muse, mutect2
- DTX4 | c.*2732T>G | 3'UTR (SNP) | VAF 8/13 reads (62%) | called by muse, mutect2, varscan2
- EMX1 | c.*608G>C | 3'UTR (SNP) | VAF 5/67 reads (7%) | called by muse, mutect2
- FAM171B | c.*738C>T | 3'UTR (SNP) | VAF 10/178 reads (6%) | called by muse, mutect2
- FBXL2 | c.*159T>A | 3'UTR (SNP) | VAF 70/115 reads (61%) | called by muse, mutect2, varscan2
- FOXP2 | c.*2885G>T | 3'UTR (SNP) | VAF 29/79 reads (37%) | catalogued as rs1291313903; called by muse, mutect2, varscan2
- GABRG1 | c.*2021G>A | 3'UTR (SNP) | VAF 9/134 reads (7%) | catalogued as rs1305179984; called by muse, mutect2
- GABRG2 | c.1249-523T>C | Intron (SNP) | VAF 22/43 reads (51%) | called by muse, mutect2, varscan2
- GAS2 | c.*153T>A | 3'UTR (SNP) | VAF 5/78 reads (6%) | called by muse, mutect2
- GDPD5 | c.375+38G>T | Intron (SNP) | VAF 8/179 reads (4%) | called by muse, mutect2
- GLP2R | c.*563G>A | 3'UTR (SNP) | VAF 10/102 reads (10%) | called by muse, mutect2
- GNG12 | c.*3511G>T | 3'UTR (SNP) | VAF 55/87 reads (63%) | called by muse, mutect2, varscan2
- GNGT1 | c.97-276T>A | Intron (SNP) | VAF 31/53 reads (58%) | called by muse, mutect2, varscan2
- GUCY1A1 | c.*3A>G | 3'UTR (SNP) | VAF 58/125 reads (46%) | catalogued as rs1401323328; called by muse, mutect2, varscan2
- HEG1 | c.*369C>A | 3'UTR (SNP) | VAF 9/106 reads (8%) | called by muse, mutect2
- HIVEP2 | c.*294G>A | 3'UTR (SNP) | VAF 7/135 reads (5%) | catalogued as rs1025262494; called by muse, mutect2
- HMGA2 | c.250-36071A>T | Intron (SNP) | VAF 39/66 reads (59%) | called by muse, mutect2, varscan2
- HOXC13 | c.*550_*552del | 3'UTR (DEL) | VAF 12/113 reads (11%) | called by mutect2, pindel
- HSPA12A | c.*1413T>G | 3'UTR (SNP) | VAF 29/51 reads (57%) | called by muse, mutect2, varscan2
- IFIT2 | c.*520T>G | 3'UTR (SNP) | VAF 10/85 reads (12%) | called by muse, mutect2
- JCAD | c.*3324C>A | 3'UTR (SNP) | VAF 46/92 reads (50%) | called by muse, mutect2, varscan2
- KAT6A | c.1483-2465T>A | Intron (SNP) | VAF 5/79 reads (6%) | called by muse, mutect2
- LINC01565 | n.1985G>A | RNA (SNP) | VAF 6/76 reads (8%) | called by muse, mutect2
- LRMDA | c.131+114020T>G | Intron (SNP) | VAF 13/80 reads (16%) | catalogued as rs749541111; called by muse, mutect2, varscan2
- LUZP2 | c.*1208A>C | 3'UTR (SNP) | VAF 38/134 reads (28%) | called by muse, mutect2, varscan2
- MIR3663 | n.95C>T | RNA (SNP) | VAF 5/39 reads (13%) | called by muse, mutect2
- NAP1L5 | c.*306_*326del | 3'UTR (DEL) | VAF 11/56 reads (20%) | called by mutect2, pindel, varscan2
- NEGR1 | c.*3680A>C | 3'UTR (SNP) | VAF 53/114 reads (46%) | called by muse, mutect2, varscan2
- OXNAD1 | c.*1011A>G | 3'UTR (SNP) | VAF 33/71 reads (46%) | called by muse, mutect2, varscan2
- PHF20L1 | c.508-202G>A | Intron (SNP) | VAF 21/47 reads (45%) | called by muse, mutect2, varscan2
- PPP1R16B | c.*1451C>T | 3'UTR (SNP) | VAF 47/94 reads (50%) | called by muse, mutect2, varscan2
- PRRX1 | c.599+1384G>T | Intron (SNP) | VAF 29/162 reads (18%) | called by muse, mutect2, varscan2
- PTPN4 | c.*1322T>A | 3'UTR (SNP) | VAF 8/46 reads (17%) | called by muse, mutect2, varscan2
- RASA3 | c.*793T>A | 3'UTR (SNP) | VAF 8/49 reads (16%) | called by muse, mutect2, varscan2
- RBM25 | c.*1287T>C | 3'UTR (SNP) | VAF 7/161 reads (4%) | called by muse, mutect2
- RBM41 | c.*331A>T | 3'UTR (SNP) | VAF 3/36 reads (8%) | called by muse, mutect2
- RGS3 | c.897+3392G>A | Intron (SNP) | VAF 43/100 reads (43%) | called by muse, mutect2, varscan2
- RPN1 | c.*182del | 3'UTR (DEL) | VAF 14/104 reads (13%) | catalogued as rs144622086; called by pindel, varscan2
- RRAS2 | c.*1303T>C | 3'UTR (SNP) | VAF 40/320 reads (13%) | called by muse, mutect2, varscan2
- SAR1B | c.*77A>C | 3'UTR (SNP) | VAF 55/557 reads (10%) | called by muse, mutect2
- SEMA3D | c.*266del | 3'UTR (DEL) | VAF 32/85 reads (38%) | called by mutect2, pindel, varscan2
- SERTAD4 | c.*2436C>T | 3'UTR (SNP) | VAF 47/98 reads (48%) | catalogued as COSV65400413; called by muse, mutect2, varscan2
- SHISA7 | c.*1626C>T | 3'UTR (SNP) | VAF 16/49 reads (33%) | called by muse, mutect2, varscan2
- SIM1 | chr6:100387093 T>C | 3'Flank (SNP) | VAF 8/132 reads (6%) | called by muse, mutect2
- SLC4A3 | c.*159C>T | 3'UTR (SNP) | VAF 8/252 reads (3%) | catalogued as rs1445809494; called by muse, mutect2
- SLC5A7 | c.*171C>T | 3'UTR (SNP) | VAF 10/132 reads (8%) | catalogued as rs1393870100; called by muse, mutect2
- SPAG16 | c.*43T>A | 3'UTR (SNP) | VAF 24/52 reads (46%) | called by muse, mutect2, varscan2
- SRRM4 | c.*400C>A | 3'UTR (SNP) | VAF 8/104 reads (8%) | called by muse, mutect2
- SVIP | c.*1549T>C | 3'UTR (SNP) | VAF 54/97 reads (56%) | called by muse, mutect2, varscan2
- TLN2 | c.137-81G>T | Intron (SNP) | VAF 14/54 reads (26%) | called by muse, mutect2
- TMBIM6 | c.-31+822T>G | Intron (SNP) | VAF 5/20 reads (25%) | called by muse, mutect2
- TMEM87B | c.*580T>C | 3'UTR (SNP) | VAF 8/84 reads (10%) | called by muse, mutect2
- TSC1 | c.*3783A>G | 3'UTR (SNP) | VAF 59/103 reads (57%) | called by muse, mutect2, varscan2
- USP31 | c.*4876C>T | 3'UTR (SNP) | VAF 35/64 reads (55%) | catalogued as rs1482562882; called by muse, mutect2, varscan2
- VPS50 | c.*379T>G | 3'UTR (SNP) | VAF 7/68 reads (10%) | called by muse, mutect2, varscan2
- WSCD2 | c.*2020G>C | 3'UTR (SNP) | VAF 11/65 reads (17%) | called by muse, mutect2, varscan2
- ZNF527 | c.*2698G>T | 3'UTR (SNP) | VAF 3/23 reads (13%) | called by muse, mutect2
